Somatic mutation profile of tumor specimen MMRF_2782_1_BM_CD138pos (aliquot MMRF_2782_1_BM_CD138pos_T1_KHS5U_L15729) from MMRF case MMRF_2782, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.2 years (19,048 days).
Specimen MMRF_2782_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f02ac92e-6599-4468-b898-c6ab0d603e79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2782_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2782_1_PB_WBC_C3_KHS5U_L15773; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d7e5eea-5742-4197-83cf-f9169510319a

The open-access MAF lists 118 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 20, Silent 17, Intron 15, Nonsense Mutation 6, 5'Flank 5, 5'UTR 4, Frame Shift Del 2, Splice Region 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MC2R | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs104894660, CM002358, COSV59617811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MPDZ | c.4906C>T p.R1636* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as rs797045095, COSV100056263; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 33/113 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL7A | c.91T>A p.W31R | Missense Mutation (SNP) | VAF 95/122 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs756357727; called by muse, mutect2, varscan2
- CSMD3 | c.8693C>T p.T2898I (on ENST00000297405 / NM_001363185.1; = p.T2729I on NM_052900.3) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.718); catalogued as COSV52111551; called by muse, mutect2
- CSMD3 | c.6791G>A p.C2264Y (on ENST00000297405 / NM_001363185.1; = p.C2160Y on NM_052900.3) | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52103798; called by muse, mutect2
- DCLK2 | c.1950G>T p.W650C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56198981; called by muse, mutect2, varscan2
- DHX32 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765264694, COSV52940521, COSV52942645; called by muse, mutect2, varscan2
- FAT1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 15/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71674265; called by muse, mutect2
- FBN2 | c.8530G>A p.V2844I | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs147134796; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- IGHV2-70 | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 114/146 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs371189824; called by muse, varscan2
- IGLV3-1 | c.314A>C p.Y105S | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs185803370; called by muse, varscan2
- IGLV3-19 | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs558491447; called by muse, mutect2, varscan2
- KIR3DL1 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as rs1428812578; called by muse, mutect2, varscan2
- KRT34 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs139913573, COSV101222525; called by muse, mutect2, varscan2
- LAMB3 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779224166, COSV100620578; called by muse, mutect2, varscan2
- SIN3B | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV104372610; called by muse, mutect2
- SLCO3A1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs775241468, COSV59230207; called by muse, mutect2, varscan2
- SMARCA4 | c.4912G>A p.D1638N | Missense Mutation (SNP) | VAF 21/433 reads (5%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV60790730; called by muse, mutect2
- SORCS2 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1400465793; called by muse, mutect2, varscan2
- TMEM26 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs1017279780, COSV53262420; called by muse, mutect2
- UNC13C | c.5731G>A p.V1911I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1272120100, COSV52853801; called by muse, mutect2, varscan2
- VANGL1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146695372, CM093988; ClinVar: benign; called by muse, mutect2
- ADGRF4 | c.1823C>G p.A608G | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- AGPAT2 | c.721_729del p.V241_A243del | In Frame Del (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.2057_2058del p.F686* | Frame Shift Del (DEL) | VAF 62/294 reads (21%) | called by mutect2, pindel, varscan2
- BRF1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CAGE1 | c.2060T>G p.L687R (on ENST00000512086; = p.L551R on NM_205864.3) | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEACAM20 | c.119A>T p.D40V | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2
- CFH | c.237A>C p.K79N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CTDSPL2 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DDX56 | c.1566+3A>G | Splice Region (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- DSCAML1 | c.5072C>T p.A1691V (on ENST00000321322; = p.A1631V on NM_020693.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HAAO | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- HECTD2 | c.812G>A p.W271* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- IGHG1 | c.104_108del p.E35Gfs*63 | Frame Shift Del (DEL) | VAF 20/39 reads (51%) | called by mutect2, pindel, varscan2
- IRF2BP2 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- KRTAP21-1 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.885); called by muse, mutect2
- LRP1B | c.590T>G p.I197S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- MAFF | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MAST4 | c.5783A>G p.H1928R (on ENST00000403625 / NM_001164664.2; = p.H1739R on NM_015183.3) | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2
- MYH2 | c.3267A>C p.K1089N | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO1E | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- OXT | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3C2G | c.2356T>A p.L786I (on ENST00000676171; = p.L745I on NM_004570.5) | Missense Mutation (SNP) | VAF 121/139 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PKHD1L1 | c.12353T>C p.I4118T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- PTPRN | c.2198G>T p.G733V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- PUS7L | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 126/162 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASA1 | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- RPL10 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- SCAMP1 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.69); called by muse, mutect2
- SEL1L3 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2
- SGSM3 | c.706T>C p.Y236H | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SORCS1 | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 55/114 reads (48%) | called by muse, mutect2, varscan2
- STK26 | c.287G>A p.W96* | Nonsense Mutation (SNP) | VAF 14/17 reads (82%) | called by muse, mutect2, varscan2
- USH2A | c.7561A>G p.S2521G | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS10 | c.2901C>T p.R967= | Silent (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- ALB | c.927A>G p.E309= | Silent (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- BAG6 | c.2559C>A p.I853= (on ENST00000676571; = p.I806= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV52994407; called by mutect2, varscan2
- CCDC85A | c.1200C>T p.D400= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV68155583; called by muse, mutect2, varscan2
- COL5A1 | c.1140C>T p.T380= | Silent (SNP) | VAF 61/281 reads (22%) | catalogued as rs749315207; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABPB2 | c.594T>C p.I198= | Silent (SNP) | VAF 62/168 reads (37%) | called by muse, mutect2, varscan2
- GRIA2 | c.1113T>C p.Y371= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV52391498; called by muse, mutect2, varscan2
- HNRNPR | c.423C>G p.T141= | Silent (SNP) | VAF 40/117 reads (34%) | called by muse, mutect2, varscan2
- JAG1 | c.2979C>A p.S993= | Silent (SNP) | VAF 57/156 reads (37%) | called by muse, mutect2, varscan2
- KIF23 | c.18T>C p.A6= | Silent (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- LAMA2 | c.1392G>A p.P464= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs757589246, COSV70351249, COSV70355106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLS1 | c.1200A>G p.T400= | Silent (SNP) | VAF 54/178 reads (30%) | called by muse, mutect2, varscan2
- RHPN1 | c.1011T>A p.P337= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- RP1 | c.2835A>T p.V945= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- SEMA4C | c.801C>G p.G267= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV59690992; called by muse, mutect2, varscan2
- TRMT11 | c.54T>C p.H18= | Silent (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- VPS18 | c.1887C>T p.A629= | Silent (SNP) | VAF 72/332 reads (22%) | called by muse, mutect2, varscan2
- ADRB1 | c.*313del | 3'UTR (DEL) | VAF 16/48 reads (33%) | catalogued as rs1345927185; called by mutect2, pindel, varscan2
- ANKDD1A | c.1483+1096del | Intron (DEL) | VAF 30/153 reads (20%) | catalogued as COSV63088008; called by mutect2, pindel, varscan2
- AP000769.5 | chr11:65498079 T>C | 5'Flank (SNP) | VAF 171/284 reads (60%) | called by muse, mutect2, varscan2
- APOBEC3G | chr22:39077261 G>A | 5'Flank (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2
- APOBEC3G | chr22:39077263 T>G | 5'Flank (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2
- BBS9 | c.*60A>T | 3'UTR (SNP) | VAF 61/237 reads (26%) | catalogued as rs1369375693; called by muse, mutect2, varscan2
- BRI3BP | c.*805T>C | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- C10orf90 | c.-47G>T | 5'UTR (SNP) | VAF 60/177 reads (34%) | called by muse, mutect2, varscan2
- CCDC158 | c.1029+3873T>G | Intron (SNP) | VAF 72/191 reads (38%) | called by muse, mutect2, varscan2
- CCKBR | c.403+42C>T | Intron (SNP) | VAF 8/227 reads (4%) | catalogued as rs1249516602; called by muse, mutect2
- CREB1 | c.881+4038G>C | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- CYTH2 | c.19+91G>A | Intron (SNP) | VAF 81/178 reads (46%) | called by muse, mutect2, varscan2
- DCC | c.*3224T>C | 3'UTR (SNP) | VAF 16/45 reads (36%) | catalogued as rs1393636518; called by muse, mutect2, varscan2
- DOCK8 | c.*23A>G | 3'UTR (SNP) | VAF 186/349 reads (53%) | catalogued as rs1446269193; called by muse, mutect2, varscan2
- DONSON | c.*234_*257del | 3'UTR (DEL) | VAF 28/144 reads (19%) | called by mutect2, pindel
- EXOC4 | c.1417+4000A>T | Intron (SNP) | VAF 15/247 reads (6%) | catalogued as COSV54093857; called by muse, mutect2
- GASK1B | c.-205T>G | 5'UTR (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- HAND1 | c.*511G>A | 3'UTR (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- KIF3B | c.*2426G>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- KLF7 | c.*5384T>G | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- KRTAP5-10 | c.*51T>G | 3'UTR (SNP) | VAF 222/409 reads (54%) | called by muse, mutect2, varscan2
- LCP1 | c.*755G>C | 3'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- MAP3K9 | c.*1747C>A | 3'UTR (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851307 T>C | 5'Flank (SNP) | VAF 186/323 reads (58%) | catalogued as rs567247750; called by muse, mutect2, varscan2
- MKRN1 | c.*216_*217del | 3'UTR (DEL) | VAF 54/256 reads (21%) | called by mutect2, pindel, varscan2
- NOTCH2NLR | c.*45T>C | 3'UTR (SNP) | VAF 45/137 reads (33%) | called by muse, varscan2
- NT5C2 | c.102-13966T>C | Intron (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- PDGFD | chr11:104164352 C>T | 5'Flank (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- PEPD | c.671+214G>T | Intron (SNP) | VAF 17/27 reads (63%) | called by mutect2, varscan2
- PLXDC2 | c.-77G>T | 5'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- PRSS22 | c.*249G>A | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- RCC1 | c.-261-699T>C | Intron (SNP) | VAF 36/90 reads (40%) | catalogued as rs747067701; called by muse, mutect2
- REG1A | c.-46-147A>C | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- RIOX2 | c.785+57C>T | Intron (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- RRAGD | c.*2352G>T | 3'UTR (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- SCRN1 | c.342-3059T>C | Intron (SNP) | VAF 14/280 reads (5%) | catalogued as rs1308562088; called by muse, mutect2
- SDK2 | c.*2409T>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as rs1159719364; called by muse, varscan2
- SNX20 | chr16:50667581 G>A | 3'Flank (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- SPTBN4 | c.5084+70C>T | Intron (SNP) | VAF 8/153 reads (5%) | catalogued as rs1296507222; called by muse, mutect2
- TFCP2L1 | c.*2995G>A | 3'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- THUMPD2 | c.673-593G>A | Intron (SNP) | VAF 72/194 reads (37%) | called by muse, mutect2, varscan2
- TLE1 | c.577+305T>A | Intron (SNP) | VAF 24/400 reads (6%) | called by muse, mutect2
- TLE3 | c.-1107G>A | 5'UTR (SNP) | VAF 42/180 reads (23%) | called by muse, varscan2
- WNT1 | c.*10C>T | 3'UTR (SNP) | VAF 39/124 reads (31%) | called by muse, mutect2, varscan2
- ZSCAN23 | c.*1147C>T | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
